Somatic mutation profile of tumor specimen TCGA-N5-A4RT-01A (aliquot TCGA-N5-A4RT-01A-11D-A28R-08) from TCGA case TCGA-N5-A4RT, project TCGA-UCS (Uterine Carcinosarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mullerian mixed tumor; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIC1; Age at diagnosis: 69.5 years (25,386 days).
Specimen TCGA-N5-A4RT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cdcac8ec-446f-463d-b21d-e117c9681723.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-N5-A4RT-10A (Blood Derived Normal), aliquot TCGA-N5-A4RT-10A-01D-A28U-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0af1c35c-a5f8-472e-9e43-e225f8792fc8

The open-access MAF lists 103 somatic variants for this specimen: 77 protein-altering or splice-affecting, 21 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 67, Silent 21, Nonsense Mutation 4, Splice Site 3, Frame Shift Del 3, RNA 2, Intron 1, 3'Flank 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BCOR | c.2926C>T p.R976* | Nonsense Mutation (SNP) | VAF 6/25 reads (24%) | catalogued as rs121434619, CM040984, COSV60709955; ClinVar: pathogenic; called by muse, varscan2
- FBXW7 | c.1154C>T p.T385I (on ENST00000281708 / NM_001349798.2; = p.T305I on NM_018315.5) | Missense Mutation (SNP) | VAF 25/43 reads (58%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55908615, COSV99029538; called by muse, mutect2, varscan2
- PIK3CA | c.1034A>T p.N345I | Missense Mutation (SNP) | VAF 71/73 reads (97%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519938, COSV55881772, COSV55902438, COSV55902706; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.722C>A p.S241Y | Missense Mutation (SNP) | VAF 39/42 reads (93%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934573, CM1212186, CM920673, COSV52661688, COSV52662386, COSV52713934, COSV52760886; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ANKFN1 | c.2043C>G p.Y681* | Nonsense Mutation (SNP) | VAF 40/113 reads (35%) | catalogued as COSV59444671; called by muse, mutect2, varscan2
- ASGR2 | c.356G>A p.G119D | Missense Mutation (SNP) | VAF 29/30 reads (97%) | SIFT tolerated (0.24); PolyPhen benign (0.05); catalogued as rs776949267; called by muse, mutect2, varscan2
- CDHR5 | c.626C>T p.P209L | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT tolerated (0.31); PolyPhen benign (0.027); catalogued as rs774600340; called by muse, mutect2, varscan2
- CFAP74 | c.4653+1G>T p.X1551_splice | Splice Site (SNP) | VAF 29/100 reads (29%) | catalogued as rs375697801; called by muse, mutect2, varscan2
- CHD4 | c.3979C>T p.R1327C (on ENST00000357008 / NM_001363606.2; = p.R1340C on NM_001273.5) | Missense Mutation (SNP) | VAF 70/182 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV58896099, COSV58902501; called by muse, mutect2, varscan2
- CNPY2 | c.305G>A p.R102H | Missense Mutation (SNP) | VAF 120/233 reads (52%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.976); catalogued as rs886916815, COSV56264277; called by muse, mutect2, varscan2
- CPNE4 | c.583C>T p.R195* | Nonsense Mutation (SNP) | VAF 19/48 reads (40%) | catalogued as COSV101456747, COSV70190669; called by muse, mutect2, varscan2
- DHRS7B | c.199+1G>T p.X67_splice | Splice Site (SNP) | VAF 18/18 reads (100%) | catalogued as rs761993168; called by muse, varscan2
- DSP | c.4620del p.I1540Mfs*12 | Frame Shift Del (DEL) | VAF 53/238 reads (22%) | catalogued as COSV65791161; called by mutect2, pindel, varscan2
- EIF4B | c.1790C>G p.S597C | Missense Mutation (SNP) | VAF 26/106 reads (25%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.015); catalogued as COSV100016744; called by muse, mutect2, varscan2
- GMCL1 | c.1324G>A p.G442R | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.012); catalogued as rs777576316; called by muse, mutect2, varscan2
- HCRTR2 | c.808C>A p.Q270K | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT tolerated (0.36); PolyPhen benign (0.029); catalogued as rs1188186465; called by muse, mutect2, varscan2
- HDAC10 | c.1168G>T p.A390S | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT tolerated (0.39); PolyPhen benign (0.013); catalogued as COSV50561142; called by muse, mutect2
- HECTD4 | c.10184G>A p.R3395H | Missense Mutation (SNP) | VAF 19/115 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as COSV101106919; called by muse, mutect2, varscan2
- HOXA4 | c.745G>A p.A249T | Missense Mutation (SNP) | VAF 61/123 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs577912292, COSV57825396; called by muse, mutect2, varscan2
- IGLC3 | c.286G>A p.V96M | Missense Mutation (SNP) | VAF 28/63 reads (44%) | PolyPhen benign (0.17); catalogued as rs758947730; called by muse, mutect2, varscan2
- LYPLA2 | c.691_694del p.V231Nfs*2 | Frame Shift Del (DEL) | VAF 9/29 reads (31%) | catalogued as rs752665083; called by mutect2, pindel, varscan2
- MAD1L1 | c.1582C>G p.R528G | Missense Mutation (SNP) | VAF 11/102 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.489); catalogued as COSV56226118; called by muse, mutect2, varscan2
- MAP4K2 | c.1738C>T p.R580C | Missense Mutation (SNP) | VAF 21/107 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs148240107; called by muse, mutect2, varscan2
- MUC16 | c.28632A>T p.K9544N | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.373); catalogued as rs778848903; called by muse, mutect2, varscan2
- MUC17 | c.2317G>A p.D773N | Missense Mutation (SNP) | VAF 113/390 reads (29%) | SIFT tolerated (0.6); PolyPhen benign (0.134); catalogued as COSV60303278; called by muse, mutect2, varscan2
- MYH1 | c.3419G>A p.R1140H | Missense Mutation (SNP) | VAF 52/61 reads (85%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.665); catalogued as rs779598062, COSV56846716; called by muse, mutect2, varscan2
- NDNF | c.901G>A p.V301I | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs754730831, COSV65633731; called by muse, mutect2, varscan2
- NXPE3 | c.1015C>T p.R339C | Missense Mutation (SNP) | VAF 38/77 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.634); catalogued as rs147008534, COSV56290723; called by muse, mutect2, varscan2
- RYR2 | c.13805G>C p.R4602P | Missense Mutation (SNP) | VAF 16/27 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100773293, COSV63712107; called by muse, mutect2, varscan2
- SLC4A5 | c.715+1G>A p.X239_splice | Splice Site (SNP) | VAF 18/69 reads (26%) | catalogued as COSV61028296; called by muse, mutect2, varscan2
- TRIM56 | c.163C>T p.R55C | Missense Mutation (SNP) | VAF 29/105 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs773591888; called by muse, mutect2, varscan2
- AFTPH | c.1601G>T p.G534V | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.564); called by muse, mutect2, varscan2
- AP1S2 | c.250C>A p.H84N | Missense Mutation (SNP) | VAF 40/111 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ASH2L | c.1325A>T p.Q442L | Missense Mutation (SNP) | VAF 41/69 reads (59%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- BCHE | c.973G>T p.D325Y | Missense Mutation (SNP) | VAF 60/62 reads (97%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.668); called by muse, mutect2, varscan2
- CDH9 | c.2333C>T p.A778V | Missense Mutation (SNP) | VAF 137/210 reads (65%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- CELSR1 | c.5170G>C p.E1724Q | Missense Mutation (SNP) | VAF 46/49 reads (94%) | SIFT tolerated (0.47); PolyPhen benign (0.348); called by muse, mutect2, varscan2
- CLPTM1L | c.1544T>G p.V515G | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL15A1 | c.4028G>T p.R1343L | Missense Mutation (SNP) | VAF 13/121 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CSMD3 | c.7967A>G p.Y2656C (on ENST00000297405 / NM_001363185.1; = p.Y2552C on NM_052900.3) | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CUBN | c.10013A>C p.Q3338P | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.607); called by muse, mutect2, varscan2
- CYP2S1 | c.931G>T p.V311F | Missense Mutation (SNP) | VAF 38/133 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.351); called by muse, mutect2, varscan2
- ENPP2 | c.1214C>G p.P405R (on ENST00000075322 / NM_001040092.3; = p.P457R on NM_006209.5) | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- EPAS1 | c.923G>A p.R308Q | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GSPT2 | c.344A>G p.E115G | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- IL1B | c.646G>T p.V216F | Missense Mutation (SNP) | VAF 6/99 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- KANSL3 | c.1633G>A p.V545M | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- LETM2 | c.1100C>A p.T367K (on ENST00000379957 / NM_001286819.2; = p.T272K on NM_144652.3) | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT tolerated (0.98); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- MAT2A | c.127G>C p.D43H | Missense Mutation (SNP) | VAF 22/108 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MCAM | c.1279A>C p.I427L | Missense Mutation (SNP) | VAF 71/77 reads (92%) | SIFT deleterious (0.01); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- MED12 | c.4034A>C p.K1345T | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.33); PolyPhen benign (0.205); called by muse, mutect2, varscan2
- MRC1 | c.3412A>T p.S1138C | Missense Mutation (SNP) | VAF 112/534 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- MYBPC3 | c.2297T>A p.V766D | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NBN | c.1798_1808del p.N600Qfs*2 | Frame Shift Del (DEL) | VAF 34/74 reads (46%) | called by mutect2, pindel*, varscan2*
- NOD2 | c.1441G>C p.G481R | Missense Mutation (SNP) | VAF 44/112 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NPEPPS | c.2125G>T p.V709F | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.468); called by muse, mutect2, varscan2
- NYAP2 | c.245G>T p.G82V | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT tolerated (0.78); PolyPhen possibly damaging (0.559); called by muse, mutect2, varscan2
- OGA | c.2535G>C p.M845I | Missense Mutation (SNP) | VAF 47/52 reads (90%) | SIFT tolerated (0.52); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR2S2 | c.745G>C p.V249L | Missense Mutation (SNP) | VAF 61/110 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- OR2W3 | c.226A>G p.S76G | Missense Mutation (SNP) | VAF 9/232 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.047); called by muse, mutect2
- PGLYRP4 | c.813C>A p.D271E | Missense Mutation (SNP) | VAF 38/105 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- PKDREJ | c.1468T>G p.F490V | Missense Mutation (SNP) | VAF 51/111 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- POLR1A | c.2640C>A p.C880* | Nonsense Mutation (SNP) | VAF 6/43 reads (14%) | called by muse, mutect2, varscan2
- PPP6R3 | c.103C>G p.Q35E | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- PRDM5 | c.613G>T p.G205W | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- REV3L | c.8075A>C p.E2692A | Missense Mutation (SNP) | VAF 27/54 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SF3B1 | c.305A>C p.D102A | Missense Mutation (SNP) | VAF 39/56 reads (70%) | SIFT deleterious (0.01); PolyPhen benign (0.117); called by muse, mutect2, varscan2
- SFPQ | c.1927G>A p.E643K | Missense Mutation (SNP) | VAF 17/104 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- SRBD1 | c.740G>C p.R247P | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TACC3 | c.663G>C p.E221D | Missense Mutation (SNP) | VAF 16/145 reads (11%) | SIFT tolerated (0.42); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- TBC1D9 | c.1922G>A p.G641D | Missense Mutation (SNP) | VAF 45/126 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRHDE | c.1817C>G p.T606R | Missense Mutation (SNP) | VAF 31/66 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- WDR45 | c.446A>T p.D149V (on ENST00000376372 / NM_001029896.2; = p.D150V on NM_007075.3) | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ZBTB38 | c.2443A>G p.I815V | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.035); called by muse, mutect2
- ZBTB7B | c.1195G>C p.E399Q (on ENST00000292176; = p.E433Q on NM_001252406.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 51/129 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ZNF234 | c.535G>A p.D179N | Missense Mutation (SNP) | VAF 36/119 reads (30%) | SIFT tolerated (0.5); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- ZNF683 | c.604C>A p.P202T | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- CHM | c.951G>A p.E317= | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as COSV63300871; called by muse, mutect2, varscan2
- COL19A1 | c.804C>A p.A268= | Silent (SNP) | VAF 6/90 reads (7%) | called by muse, mutect2
- DHX9 | c.2679C>T p.F893= | Silent (SNP) | VAF 54/102 reads (53%) | called by muse, mutect2, varscan2
- FAM186B | c.58C>T p.L20= | Silent (SNP) | VAF 10/33 reads (30%) | called by muse, mutect2, varscan2
- HCN1 | c.1080G>T p.G360= | Silent (SNP) | VAF 29/129 reads (22%) | called by muse, mutect2, varscan2
- MED12 | c.5541A>G p.P1847= | Silent (SNP) | VAF 9/23 reads (39%) | called by muse, mutect2, varscan2
- NPC1L1 | c.2013C>A p.G671= | Silent (SNP) | VAF 19/89 reads (21%) | called by muse, mutect2, varscan2
- NR2F2 | c.1044C>T p.Y348= | Silent (SNP) | VAF 103/148 reads (70%) | catalogued as rs368117658; called by muse, mutect2, varscan2
- OR56B4 | c.429T>G p.T143= | Silent (SNP) | VAF 26/85 reads (31%) | called by muse, mutect2, varscan2
- PLCXD1 | c.852C>T p.V284= | Silent (SNP) | VAF 9/88 reads (10%) | catalogued as rs760603058; called by muse, mutect2, varscan2
- PLPPR1 | c.957G>A p.A319= | Silent (SNP) | VAF 7/20 reads (35%) | catalogued as rs371737348; called by muse, mutect2, varscan2
- POMT1 | c.36G>C p.T12= | Silent (SNP) | VAF 47/52 reads (90%) | called by muse, mutect2, varscan2
- PRDM9 | c.1584G>A p.E528= | Silent (SNP) | VAF 50/109 reads (46%) | catalogued as rs745775729; called by muse, mutect2, varscan2
- RASIP1 | c.2247C>T p.G749= | Silent (SNP) | VAF 39/127 reads (31%) | catalogued as rs1027710127, COSV55803753; called by muse, mutect2, varscan2
- RYR2 | c.13806A>G p.R4602= | Silent (SNP) | VAF 16/27 reads (59%) | catalogued as rs1230311017; called by muse, mutect2, varscan2
- RYR3 | c.6915C>A p.I2305= (on ENST00000389232; = p.I2306= on NM_001036.6) | Silent (SNP) | VAF 6/12 reads (50%) | called by muse, mutect2, varscan2
- SLC17A5 | c.84G>T p.R28= | Silent (SNP) | VAF 3/10 reads (30%) | called by muse, mutect2
- TIAM1 | c.3627G>A p.A1209= | Silent (SNP) | VAF 35/136 reads (26%) | catalogued as rs367873088; called by muse, mutect2, varscan2
- TMEM81 | c.57G>C p.L19= | Silent (SNP) | VAF 38/81 reads (47%) | called by muse, mutect2, varscan2
- TTN | c.6975C>G p.V2325= (on ENST00000591111; = p.V2279= on NM_003319.4) | Silent (SNP) | VAF 20/77 reads (26%) | called by muse, mutect2, varscan2
- ZNF518B | c.2457G>A p.A819= | Silent (SNP) | VAF 20/96 reads (21%) | catalogued as rs201909475; called by muse, mutect2, varscan2
- AC005863.1 | n.400A>T | RNA (SNP) | VAF 10/22 reads (45%) | called by muse, varscan2
- DENND10P1 | n.1145A>C | RNA (SNP) | VAF 24/93 reads (26%) | called by muse, mutect2, varscan2
- GBA3 | c.59-8317T>G | Intron (SNP) | VAF 25/213 reads (12%) | catalogued as rs1468693431; called by muse, mutect2, varscan2
- MTRNR2L6 | chr7:142671047 C>A | 3'Flank (SNP) | VAF 41/92 reads (45%) | called by muse, mutect2, varscan2
- WT1 | chr11:32439046 C>A | 5'Flank (SNP) | VAF 16/42 reads (38%) | called by muse, mutect2, varscan2
